Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A459, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A459-01A (Primary Tumor).

Procurement Date: Laterality: Tumor cells form the trabecular patterns, or acinar or sheets patterns intervening in benign tissue. Tumor invades in stroma. The tumor cells retain apolygonal shape and have round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are abundant and the cytoplasm is eosinophilic. Nuclei are irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor is necrotic and invasion of lymphocytes.

Path Report: LIVER TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor size: 6 x 5 x 5 cm

Focality: Not specified

Histologic type: Hepatocellular carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Single tumor with no invasion

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O3
carcinoma, hepatocellular, NOS
817013

Site: liver

C22.0

8/31/12
RD

Reviewed: 8/14/12		

Source: NCI Genomic Data Commons file 6155dd39-d3a4-44aa-a5f4-cddd6e556453 (TCGA-ED-A459.289EC60C-0AAB-4E61-A8AB-A199D4663AE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).